Gene-level copy-number profile of tumor specimen TCGA-27-2528-01A from TCGA case TCGA-27-2528, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.6 years (22,867 days).
Specimen TCGA-27-2528-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.21655f02-c537-4847-bb9c-f74e319af0d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-27-2528-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07454f8f-47b6-45ed-9a71-bcf70bb48a92

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 5,412; copy number 2: 49,714; copy number 3: 4,276; copy number 4: 319; copy number 18: 3; copy number 25: 57; copy number 26: 9; copy number 36: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-27-2528-01A-01D-0784-01): tumor purity 0.77, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,128,103, 16 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 83 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:28,279,211–28,825,894, 2 genes, copy number 26 (within-gene range 4–26): PPIAP80, CREB5.
- chr7:28,953,358–29,195,451, 7 genes, copy number 26 (within-gene range 2–26): TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1.
- chr7:30,852,273–30,993,254, 3 genes, copy number 18 (within-gene range 4–18): AC004691.2, AQP1, GHRHR.
- chr7:54,933,699–55,211,628, 3 genes, copy number 25: AC006971.1, EGFR, EGFR-AS1.
- chr7:128,739,292–130,442,433, 56 genes, copy number 25–36: CALU, RN7SL81P, OPN1SW, CCDC136, FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB, AC025594.1, IRF5, AC025594.2, TNPO3, RN7SL306P, ODCP, TPI1P2, AC018639.1, AC011005.2, AC011005.3, CYCSP20, AC011005.1, TSPAN33, RNY1P11, SMO, AC011005.4, AHCYL2, AC009244.1, CDC26P1, STRIP2, SNRPGP3, RNU1-72P, SMKR1, AC078846.1, NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41.
- chr7:150,944,961–151,083,493, 12 genes, copy number 25: KCNH2, NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1.

Autosomal genes at a single copy (total copy number 1): 3,032. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
